Somatic mutation profile of tumor specimen MP2PRT-PARXKE-TMP1-A (aliquot MP2PRT-PARXKE-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARXKE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (824 days).
Specimen MP2PRT-PARXKE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9c90cf3-badd-423d-bfd2-d899e9e6fe97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXKE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXKE-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27e5cd06-5452-4716-83be-cee4112744aa

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLCO1A2 | c.698T>A p.I233N | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs373302390; called by muse, mutect2, varscan2
- TDRD12 | c.77del p.L26* | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | catalogued as rs1483524118; called by pindel, varscan2
- VEGFC | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs566826535, COSV54604159; called by muse, mutect2, varscan2
- TEX13A | c.744C>A p.L248= | Silent (SNP) | VAF 136/586 reads (23%) | called by muse, mutect2, varscan2
